Somatic mutation profile of tumor specimen TCGA-44-7661-01A (aliquot TCGA-44-7661-01A-11D-2063-08) from TCGA case TCGA-44-7661, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.8 years (25,483 days).
Specimen TCGA-44-7661-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4da39cd3-7acc-4cc1-b877-1220d09f0bdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7661-10A (Blood Derived Normal), aliquot TCGA-44-7661-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28b17e7d-8b8b-42c4-acc7-9397f52c1773

The open-access MAF lists 271 somatic variants for this specimen: 208 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 55, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 6, RNA 4, Intron 3, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1962C>G p.F654L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55535794, COSV55540637; called by muse, mutect2, varscan2
- ACBD5 | c.559G>T p.V187F (on ENST00000375888 / NM_001352568.1; = p.V178F on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV65521364; called by muse, mutect2, varscan2
- ADAMTS12 | c.4777G>A p.E1593K | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV61280815; called by muse, mutect2, varscan2
- ADD1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53266702; called by muse, mutect2, varscan2
- AFF2 | c.2485A>T p.K829* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV54008611; called by muse, mutect2, varscan2
- AGAP2 | c.2037A>T p.K679N (on ENST00000547588 / NM_001122772.2; = p.K343N on NM_014770.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57732297; called by muse, mutect2, varscan2
- AGXT | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56753911; called by muse, mutect2, varscan2
- AHNAK | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV57211729, COSV57231535; called by muse, mutect2
- AHNAK2 | c.15760G>A p.D5254N | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV60931595; called by muse, mutect2
- AHNAK2 | c.14836C>A p.H4946N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as COSV60931606; called by muse, mutect2, varscan2
- AKAP9 | c.9772A>T p.S3258C (on ENST00000359028; = p.S3234C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62358539; called by muse, mutect2, varscan2
- ALG9 | c.789+2T>C p.X263_splice | Splice Site (SNP) | VAF 19/81 reads (23%) | catalogued as COSV67645555; called by muse, mutect2, varscan2
- ALPK2 | c.3689G>T p.W1230L | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV64495071, COSV64497447; called by muse, mutect2, varscan2
- AMHR2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM151253, COSV57687076; called by muse, mutect2, varscan2
- ANO1 | c.2119G>T p.V707L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV60289622; called by muse, mutect2, varscan2
- APC | c.3295G>C p.V1099L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.079); catalogued as CD930895, COSV57381507, COSV57384626; called by muse, mutect2, varscan2
- ARR3 | c.733A>C p.K245Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as rs1302641965, COSV52105329; called by muse, mutect2, varscan2
- ATP13A4 | c.585G>C p.W195C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55075169, COSV55075573; called by muse, mutect2
- BAHCC1 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV57033636; called by muse, mutect2, varscan2
- BCORL1 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.063); catalogued as rs190993389, COSV54407784; called by muse, mutect2, varscan2
- BLVRA | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55516517; called by muse, mutect2, varscan2
- BPTF | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV58847418; called by muse, mutect2
- BTK | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as CM980272, COSV58123931; called by muse, mutect2
- BUB1 | c.1937T>C p.V646A | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV57067408; called by muse, mutect2, varscan2
- CAMSAP2 | c.3103G>T p.D1035Y (on ENST00000236925 / NM_001297707.2; = p.D1024Y on NM_203459.3) | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV52677687; called by muse, mutect2, varscan2
- CBLN3 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199897938, COSV52159925; called by muse, mutect2, varscan2
- CEP126 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54830966; called by muse, mutect2
- CEP41 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.639); catalogued as COSV56221575; called by muse, mutect2
- CHL1 | c.3555C>A p.Y1185* (on ENST00000397491 / NM_001253387.1; = p.Y1201* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV56607150; called by muse, mutect2, varscan2
- CLCA2 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100991760; called by mutect2, varscan2
- CNKSR2 | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54267107; called by muse, mutect2, varscan2
- COL22A1 | c.3842C>T p.T1281I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as COSV57362024; called by muse, mutect2, varscan2
- CORO1C | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54599107; called by muse, mutect2
- CPEB1 | c.766G>C p.D256H (on ENST00000617958; = p.D196H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55618589, COSV55620785; called by muse, mutect2
- CRB1 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV66349165; called by muse, varscan2
- CRISP3 | c.701G>T p.C234F (on ENST00000371159 / NM_001368123.1; = p.C216F on NM_006061.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757797049, COSV53823375; called by muse, mutect2, varscan2
- CXCR1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs147031882; called by muse, mutect2, varscan2
- DDX10 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.528); catalogued as rs368093274; called by muse, mutect2, varscan2
- DDX4 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | catalogued as rs1450132609, COSV61754689; called by muse, mutect2
- DDX50 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.727); catalogued as COSV101007271, COSV65293411; called by muse, mutect2, varscan2
- DNAH7 | c.2543G>T p.G848V | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56787888; called by muse, mutect2
- DNAH8 | c.12955C>G p.L4319V | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV59482122; called by muse, mutect2
- DOCK4 | c.5864G>T p.R1955L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs747359632, COSV70243468; called by muse, varscan2
- DRP2 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV65809883, COSV65811930; called by muse, mutect2, varscan2
- DSC1 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV57151916; called by muse, mutect2
- DTNA | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52027000; called by muse, mutect2
- EBF2 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68779664; called by muse, mutect2, varscan2
- EIF3E | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55206189; called by muse, mutect2, varscan2
- ENOX1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99817337; called by muse, mutect2, varscan2
- EPHX4 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64890113; called by muse, mutect2, varscan2
- ESYT3 | c.916-1G>C p.X306_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as COSV56681940; called by muse, mutect2
- EVC | c.2781A>T p.L927= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV53838335, COSV99381739; called by muse, mutect2, varscan2
- EXO1 | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62220055; called by muse, mutect2, varscan2
- EYS | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60980508; called by mutect2, varscan2
- F8 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV64271187; called by muse, mutect2
- FAM83B | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV60927131; called by muse, mutect2, varscan2
- FASTKD3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV52946962; called by muse, mutect2, varscan2
- FGA | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV57401396; called by muse, mutect2, varscan2
- FST | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56817007; called by muse, mutect2, varscan2
- GABRA1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50120109; called by muse, varscan2
- GABRB2 | c.1040G>T p.S347I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV50949931; called by muse, mutect2, varscan2
- GAS7 | c.820G>C p.A274P (on ENST00000432992 / NM_201433.2; = p.A134P on NM_003644.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV60443983; called by muse, mutect2
- GRM5 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs749698738, COSV59593285; called by muse, mutect2, varscan2
- GUCY2C | c.2396T>A p.M799K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV53795850; called by muse, mutect2, varscan2
- HAO1 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV66493978; called by muse, varscan2
- HIPK2 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61232977; called by muse, mutect2
- HMMR | c.1815G>T p.Q605H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100701059; called by muse, mutect2, varscan2
- HMMR | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs200677786, COSV100701060; called by muse, mutect2, varscan2
- HRNR | c.2608C>A p.H870N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs749683897, COSV64263194; called by muse, varscan2
- IDO2 | c.810G>C p.Q270H (on ENST00000389060; = p.Q283H on NM_194294.2) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58429837; called by muse, mutect2
- IFNLR1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59527369; called by muse, mutect2
- INPP4B | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV53746816; called by muse, mutect2, varscan2
- INTS2 | c.869C>G p.A290G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52156883; called by muse, mutect2, varscan2
- IQCJ | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.017); catalogued as COSV67336445; called by muse, mutect2, varscan2
- IREB2 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51926965; called by muse, mutect2, varscan2
- KLHDC2 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.708); catalogued as COSV53588513; called by muse, mutect2, varscan2
- KLHL1 | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64784899; called by muse, mutect2
- KLHL4 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV64148245; called by muse, mutect2, varscan2
- KRTAP10-8 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV58167367; called by muse, mutect2, varscan2
- KRTAP22-1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 18/145 reads (12%) | PolyPhen probably damaging (0.983); catalogued as COSV58183060; called by muse, mutect2, varscan2
- LRFN5 | c.313C>G p.H105D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53276291; called by muse, mutect2, varscan2
- LRP1 | c.7757A>G p.N2586S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54526849; called by muse, mutect2, varscan2
- LRP1B | c.7664G>T p.G2555V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914818685, COSV101261589; called by mutect2, varscan2
- LRRC4B | c.1172T>A p.M391K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV65350872; called by muse, mutect2, varscan2
- MAP3K4 | c.4048G>T p.G1350* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV62338765; called by muse, mutect2, varscan2
- MARCHF6 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV56887296; called by muse, mutect2
- MARCHF6 | c.282T>A p.F94L | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56887307; called by muse, mutect2
- MBNL3 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV63731735; called by muse, mutect2, varscan2
- MCM10 | c.1676C>T p.S559L (on ENST00000484800 / NM_182751.3; = p.S558L on NM_018518.5) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV66336951; called by muse, mutect2, varscan2
- MCOLN1 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV99900934; called by muse, mutect2, varscan2
- MEIOB | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV58055927; called by muse, mutect2, varscan2
- MMD2 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV68661660; called by muse, mutect2, varscan2
- MRPS35 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1489736117, COSV99317477, COSV99317681; called by muse, mutect2
- MYH7 | c.4709C>A p.A1570E | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs730880807, COSV62524215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.7202A>G p.K2401R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV59149593; called by muse, varscan2
- NAV3 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57074985, COSV57113687; called by muse, mutect2, varscan2
- NCKAP5 | c.1225C>A p.Q409K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58476629; called by muse, varscan2
- NLRC4 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV61592818; called by muse, mutect2, varscan2
- NLRP14 | c.2291+1G>T p.X764_splice | Splice Site (SNP) | VAF 23/198 reads (12%) | catalogued as COSV100205464, COSV55065332; called by muse, mutect2, varscan2
- NMNAT1 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV65883242; called by muse, mutect2, varscan2
- NOS1 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV57607304, COSV57608051, COSV57622280; called by muse, mutect2, varscan2
- NOS1AP | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62640444; called by muse, mutect2, varscan2
- NPAS3 | c.1018G>T p.D340Y (on ENST00000356141 / NM_001164749.2; = p.D308Y on NM_022123.3) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100639575, COSV60863839; called by muse, mutect2, varscan2
- NRXN3 | c.2664G>T p.Q888H (on ENST00000335750 / NM_001330195.2; = p.Q515H on NM_004796.6) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59811046; called by muse, mutect2, varscan2
- NT5DC1 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV60310431; called by muse, mutect2
- OR13C2 | c.8G>C p.W3S | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV73377800; called by muse, mutect2, varscan2
- OR14I1 | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61200906; called by muse, mutect2, varscan2
- OR2A14 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV68718711; called by muse, mutect2, varscan2
- OR2W3 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456550, COSV64458077; called by muse, mutect2, varscan2
- OR4K13 | c.192C>G p.S64R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV59860968; called by muse, mutect2, varscan2
- OR51L1 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.947); catalogued as COSV58625869; called by muse, mutect2, varscan2
- OR52B6 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV61448378; called by muse, mutect2, varscan2
- OR6T1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1236618198, COSV100190098, COSV58309635; called by muse, mutect2, varscan2
- OR8I2 | c.302T>A p.M101K | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV56169347, COSV56170660; called by muse, mutect2, varscan2
- OTOL1 | c.1377C>A p.D459E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100019713, COSV60008561; called by muse, mutect2, varscan2
- PAK3 | c.1321C>A p.P441T (on ENST00000262836 / NM_001324328.2; = p.P426T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53280911; called by muse, mutect2, varscan2
- PAX7 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64750762, COSV64752964; called by muse, mutect2, varscan2
- PCDHGA8 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV54038255; called by muse, mutect2, varscan2
- PDCL3 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51810363; called by muse, mutect2, varscan2
- PIF1 | c.1498G>T p.V500L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV51424650; called by muse, mutect2, varscan2
- PKD2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52940320, COSV52941413; called by muse, mutect2, varscan2
- PKHD1 | c.7088A>T p.N2363I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61895721; called by muse, mutect2, varscan2
- PLEC | c.3250G>T p.G1084* (on ENST00000322810 / NM_201380.4; = p.G974* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV59697583; called by muse, mutect2, varscan2
- POM121 | c.1060G>C p.E354Q (on ENST00000434423; = p.E89Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1427887978, COSV57524273; called by muse, mutect2
- PPP1R17 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV59612656; called by muse, mutect2, varscan2
- PRKCB | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs1382022679, COSV57802743; called by muse, mutect2, varscan2
- PRKCZ | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66071481; called by muse, mutect2, varscan2
- PSMD3 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV52859929; called by muse, mutect2
- PSME4 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101122697; called by muse, mutect2, varscan2
- PSME4 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV101122699; called by muse, mutect2, varscan2
- PTEN | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs57374291, CM1111458, CM131884, COSV64291957, COSV64294035, COSV64296475; called by muse, mutect2, varscan2
- PTPRJ | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); catalogued as COSV69254754; called by muse, mutect2
- RAD51AP2 | c.2305C>G p.Q769E | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV67589320; called by muse, mutect2, varscan2
- RBM10 | c.43del p.R15Afs*119 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as COSV61312235; called by mutect2, pindel, varscan2
- RBPJL | c.1176+1G>A p.X392_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59215840; called by muse, mutect2
- RDH8 | c.92C>A p.S31Y (on ENST00000651512; = p.S11Y on NM_015725.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50678422, COSV50678815; called by muse, mutect2, varscan2
- ROBO2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59940690; called by muse, mutect2, varscan2
- RTL9 | c.1787C>A p.T596K | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV71825484, COSV71826477; called by muse, mutect2, varscan2
- RUBCNL | c.1902G>C p.Q634H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV59794572; called by muse, mutect2
- RXFP3 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV57508344; called by muse, mutect2, varscan2
- RYR2 | c.3914G>T p.S1305I | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV63715581; called by muse, mutect2, varscan2
- SAGE1 | c.88-2A>T p.X30_splice | Splice Site (SNP) | VAF 16/153 reads (10%) | catalogued as COSV61018342; called by muse, mutect2, varscan2
- SAMHD1 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV53428334; called by muse, mutect2, varscan2
- SCYL2 | c.1766A>T p.N589I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV62570881; called by muse, varscan2
- SEMA6A | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.373); catalogued as COSV56715182; called by muse, mutect2, varscan2
- SERPINA11 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.983); catalogued as COSV58241736; called by muse, mutect2, varscan2
- SH2D4A | c.674G>T p.S225I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV56124973; called by muse, mutect2, varscan2
- SHANK2 | c.4656G>A p.M1552I | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53589737, COSV53620008; called by muse, mutect2
- SLC22A8 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV60327205; called by muse, mutect2, varscan2
- SLC2A9 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs570722567, COSV53329231; called by muse, mutect2, varscan2
- SLC35C1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58480948; called by muse, mutect2, varscan2
- SLC8A1 | c.1217T>A p.V406D | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.874); catalogued as COSV60497357; called by muse, mutect2
- SLCO6A1 | c.1087C>A p.L363M | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV65814991; called by muse, mutect2, varscan2
- SLIT1 | c.2758C>A p.L920M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV56599723; called by muse, mutect2, varscan2
- SLITRK1 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65677736; called by muse, mutect2, varscan2
- SORBS3 | c.1526A>T p.Y509F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV53555046; called by muse, mutect2, varscan2
- SPANXC | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV62842114, COSV62842334; called by muse, varscan2
- SPTBN5 | c.5884G>T p.V1962L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV58023148; called by muse, mutect2, varscan2
- SRSF6 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV54829253; called by muse, mutect2, varscan2
- STT3A | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV67065543; called by muse, mutect2, varscan2
- SYCP2L | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51657784; called by muse, mutect2
- TAB3 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.12); catalogued as COSV55841178; called by muse, mutect2, varscan2
- TAF1D | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.23); catalogued as COSV60640094; called by muse, mutect2
- TCEAL9 | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV65489168; called by muse, mutect2, varscan2
- TCHH | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs779102502, COSV64277931; called by muse, mutect2
- TENM3 | c.5745C>A p.Y1915* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV69319997; called by muse, mutect2, varscan2
- THSD7A | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | catalogued as COSV101448697, COSV70271244, COSV70273354; called by muse, mutect2, varscan2
- TLL2 | c.3034C>T p.H1012Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV63576190; called by muse, mutect2, varscan2
- TLR8 | c.1555C>G p.Q519E (on ENST00000218032 / NM_138636.5; = p.Q537E on NM_016610.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54320890; called by muse, mutect2
- TMEM135 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs768976861, COSV59706924; called by muse, mutect2, varscan2
- TNFRSF8 | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.553); catalogued as COSV55801033; called by muse, mutect2, varscan2
- TNN | c.2651-2A>T p.X884_splice | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV53436180; called by muse, mutect2, varscan2
- TNNI2 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV53291188; called by muse, mutect2, varscan2
- TNS4 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54188180; called by muse, mutect2, varscan2
- TOP3B | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV64119293; called by muse, mutect2, varscan2
- TRRAP | c.6143G>C p.R2048T (on ENST00000359863 / NM_001244580.1; = p.R2030T on NM_003496.3) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV62854951; called by muse, mutect2, varscan2
- TSEN15 | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62294716; called by muse, mutect2, varscan2
- TXNIP | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.772); catalogued as COSV65221491; called by muse, mutect2, varscan2
- UGT2B11 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71423482; called by muse, mutect2, varscan2
- UNC13B | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV65938768; called by muse, mutect2, varscan2
- USP6NL | c.1573G>C p.V525L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53215977, COSV99509709; called by muse, mutect2, varscan2
- VEGFC | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV54607282; called by muse, mutect2, varscan2
- WDR44 | c.1796C>A p.P599Q | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54163775, COSV54169404; called by muse, mutect2, varscan2
- WNK3 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63613112; called by muse, mutect2, varscan2
- ZBTB3 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1485976879, COSV67361876; called by muse, mutect2
- ZCCHC24 | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV64887616; called by muse, mutect2
- ZFHX4 | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV51497484; called by muse, varscan2
- ZFP28 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as rs777303245, COSV56738230; called by muse, mutect2, varscan2
- ZNF266 | c.930A>T p.Q310H | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV63223295; called by muse, mutect2, varscan2
- ZNF318 | c.1766A>T p.Y589F | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV58937919; called by muse, mutect2, varscan2
- ZNF384 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1378255020, COSV60533454; called by muse, mutect2, varscan2
- ZNF528 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64621372; called by muse, mutect2, varscan2
- ZNF548 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV60240356, COSV60242032; called by muse, mutect2, varscan2
- ZNF804A | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV56472377; called by muse, mutect2, varscan2
- ZNF813 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67178164; called by muse, mutect2
- ZSCAN4 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58998967, COSV59001797; called by muse, mutect2, varscan2
- ABCA8 | c.3106del p.L1036Cfs*11 | Frame Shift Del (DEL) | VAF 26/230 reads (11%) | called by mutect2, pindel, varscan2
- DNAI4 | c.961del p.D321Ifs*16 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- DYNC2LI1 | c.256del p.E86Nfs*11 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- EDNRB | c.1030dup p.I344Nfs*46 (on ENST00000377211 / NM_001201397.1; = p.I254Nfs*46 on NM_000115.5) | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- FMN2 | c.4927del p.A1643Hfs*5 | Frame Shift Del (DEL) | VAF 17/144 reads (12%) | called by mutect2, pindel, varscan2
- GC | c.34del p.A12Hfs*6 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.5701del p.A1901Pfs*6 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- MRC1 | c.3749C>T p.S1250F | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- RIC3 | c.112_113insG p.P38Rfs*4 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.228_239del p.Y79_L82del | In Frame Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11028T>C p.N3676= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV71294980; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1725C>T p.A575= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV54470844; called by muse, mutect2
- AKAP12 | c.4884T>A p.S1628= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53569805, COSV53582549; called by muse, mutect2, varscan2
- ANKRD26 | c.2601A>G p.R867= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs549126392, COSV65778531; called by muse, mutect2, varscan2
- C1QTNF9B | c.57A>G p.S19= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV65944636; called by muse, mutect2, varscan2
- C9orf131 | c.2283C>A p.A761= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV56614353; called by muse, mutect2, varscan2
- CDH9 | c.1989C>G p.G663= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV50251548, COSV50470538; called by muse, mutect2, varscan2
- CRACD | c.3618C>A p.A1206= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV51732019; called by muse, mutect2
- CSF1R | c.666C>A p.I222= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV53829533, COSV53843591; called by muse, mutect2, varscan2
- CSMD3 | c.6396C>A p.P2132= (on ENST00000297405 / NM_001363185.1; = p.P2028= on NM_052900.3) | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV52326876; called by muse, mutect2, varscan2
- CUBN | c.5982G>T p.P1994= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV64716353, COSV64727785; called by muse, mutect2, varscan2
- DEFB119 | c.34C>T p.L12= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV59268128; called by muse, mutect2
- ENPP5 | c.525G>T p.T175= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV57910062; called by muse, mutect2
- FGF5 | c.201G>A p.L67= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs1053883049, COSV56892023; called by muse, varscan2
- GART | c.2811A>T p.T937= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs763387008, COSV67819792; called by muse, mutect2, varscan2
- GFRA1 | c.732G>A p.L244= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV62611070; called by muse, mutect2, varscan2
- GPR156 | c.1236G>T p.A412= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV59942588; called by muse, varscan2
- GRK5 | c.1650G>A p.L550= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs1282181452, COSV64867986; called by muse, mutect2
- GRM2 | c.1833T>A p.G611= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV56587608; called by muse, mutect2, varscan2
- HIVEP1 | c.7206G>T p.G2402= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV65105210; called by muse, mutect2, varscan2
- HPGDS | c.396C>T p.D132= | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as COSV54776349; called by muse, mutect2, varscan2
- IQCN | c.2505G>A p.P835= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs778575201, COSV66578147; called by mutect2, varscan2
- KCNT2 | c.3249C>A p.I1083= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as COSV54106582, COSV54110303; called by muse, mutect2, varscan2
- KRT23 | c.9C>T p.S3= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV52929151; called by muse, mutect2, varscan2
- LAMA2 | c.2736G>T p.A912= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV70355651; called by muse, mutect2, varscan2
- LRRTM1 | c.705G>T p.L235= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV54447031; called by muse, mutect2
- METAP1 | c.414G>A p.G138= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV56446164; called by muse, mutect2, varscan2
- NCAM1 | c.1194C>T p.S398= (on ENST00000316851 / NM_181351.5; = p.S388= on NM_000615.7) | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV57525416; called by muse, mutect2, varscan2
- NLRP10 | c.732C>G p.L244= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1428896811, COSV100150003, COSV60778815; called by mutect2, varscan2
- NLRP3 | c.867G>C p.V289= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV60230319, COSV60231268; called by muse, mutect2, varscan2
- NPY2R | c.438G>T p.L146= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV61529637; called by muse, mutect2, varscan2
- NRXN3 | c.1689G>A p.T563= (on ENST00000335750 / NM_001330195.2; = p.T190= on NM_004796.6) | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as rs768400919, COSV59811028; called by muse, mutect2, varscan2
- NXPH3 | c.594C>T p.I198= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV60872713; called by muse, mutect2
- OR1N2 | c.75G>A p.E25= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV65461267; called by muse, mutect2, varscan2
- OR5H6 | c.75G>T p.L25= (on ENST00000642105; = p.L9= on NM_001005479.2) | Silent (SNP) | VAF 29/238 reads (12%) | catalogued as COSV67352149; called by muse, mutect2, varscan2
- OR7A17 | c.75C>A p.P25= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV59415293; called by muse, mutect2, varscan2
- OSMR | c.2082G>T p.P694= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV57090791, COSV57092334; called by muse, mutect2, varscan2
- PMS2 | c.1245G>T p.V415= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV56224327; called by muse, mutect2, varscan2
- PNMA5 | c.804C>G p.P268= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV100721722; called by muse, mutect2
- POU6F2 | c.1206G>T p.T402= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs772962833, COSV68882951; called by muse, mutect2, varscan2
- QRICH2 | c.4596C>T p.C1532= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53155558; called by muse, mutect2
- REXO5 | c.957G>A p.L319= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as COSV54474941; called by muse, mutect2
- RFT1 | c.762G>A p.Q254= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as rs1157165255, COSV56250495; called by muse, mutect2
- RPN2 | c.1656G>T p.P552= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV52909207; called by muse, mutect2, varscan2
- SALL4 | c.1230C>T p.F410= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1193747049, COSV53852826; called by muse, mutect2
- SERPINB6 | c.984C>T p.D328= (on ENST00000612421 / NM_001271823.2; = p.D309= on NM_004568.6) | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV59567635; called by muse, mutect2, varscan2
- SLC1A6 | c.864G>A p.K288= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV55674379; called by muse, varscan2
- SMR3A | c.198C>A p.P66= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as COSV56951479; called by muse, mutect2, varscan2
- TDRD7 | c.2823G>C p.L941= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV62431112; called by muse, mutect2
- TNC | c.453C>T p.A151= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV60790843; called by muse, mutect2
- TTN | c.82092G>C p.L27364= (on ENST00000591111; = p.L19940= on NM_003319.4) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV59919739; called by muse, mutect2
- XBP1 | c.621C>T p.F207= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV53274945; called by muse, mutect2
- ZCCHC12 | c.180C>A p.T60= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV59573032; called by muse, mutect2, varscan2
- ZNF668 | c.1554C>T p.C518= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV56219460; called by muse, mutect2, varscan2
- ZNF777 | c.2052C>T p.R684= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1343576982, COSV56100441; called by muse, mutect2
- C7orf65 | n.451A>G | RNA (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.7406T>A | RNA (SNP) | VAF 24/120 reads (20%) | catalogued as COSV61780252; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446080 C>A | 3'Flank (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- LINC00922 | n.896C>A | RNA (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- MTUS1 | c.2449+1788A>T | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100030114; called by muse, mutect2, varscan2
- OR3A4P | n.1372A>G | RNA (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- PHB2 | c.711+176G>A | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99781330; called by muse, mutect2
- RAB28 | c.574-1287A>T | Intron (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99986461; called by muse, mutect2
